Somatic mutation profile of tumor specimen 0DHY4P from CCDI case PBBUXK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Intraductal papillary mucinous neoplasm with an associated invasive carcinoma; Tissue or organ of origin: Ovary; Age at diagnosis: 15.7 years (5,745 days).
Specimen 0DHY4P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d79afb38-2708-4348-94f5-89ea611a463f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHY2Q (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddbcf5e8-922c-4008-9cd5-ab970f59f376

The open-access MAF lists 91 somatic variants for this specimen: 48 protein-altering or splice-affecting, 27 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 27, Intron 8, Nonsense Mutation 7, 5'UTR 5, 3'UTR 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 220/535 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- KCNJ11 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 166/548 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80356625, CM040763, CM109650; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 227/558 reads (41%) | catalogued as rs876659384, COSV52700095, COSV52863161; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACADL | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 72/680 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52051976; called by muse, mutect2, varscan2
- CECR2 | c.2684G>A p.G895E (on ENST00000342247 / NM_001290047.2; = p.G712E on NM_001290046.1) | Missense Mutation (SNP) | VAF 40/337 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as COSV52841645; called by muse, mutect2, varscan2
- CSF2RB | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 99/558 reads (18%) | catalogued as rs1569136140; called by muse, mutect2, varscan2
- DCUN1D4 | c.818G>C p.G273A (on ENST00000334635 / NM_001287757.1; = p.G238A on NM_015115.3) | Missense Mutation (SNP) | VAF 37/673 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV58120861; called by muse, mutect2
- FLT1 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 35/754 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs779189056, COSV56719029; called by muse, mutect2
- FMO4 | c.1640G>C p.R547T | Missense Mutation (SNP) | VAF 44/451 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV63000892; called by muse, mutect2, varscan2
- KRT40 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 72/571 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100898769; called by muse, mutect2, varscan2
- PABPC1 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 81/619 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.077); catalogued as COSV59399781; called by muse, mutect2, varscan2
- PCDHGA2 | c.1990G>A p.V664M | Missense Mutation (SNP) | VAF 123/389 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.634); catalogued as rs1475554511, COSV53899507; called by muse, mutect2
- PIKFYVE | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 189/638 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374981165; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1897C>G p.P633A (on ENST00000352766; = p.P554A on NM_181334.5) | Missense Mutation (SNP) | VAF 89/530 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as rs371629439; called by muse, mutect2, varscan2
- PTPN21 | c.2554C>G p.L852V | Missense Mutation (SNP) | VAF 20/450 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100162548; called by muse, mutect2
- SKA3 | c.867C>G p.F289L | Missense Mutation (SNP) | VAF 61/660 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV100006176; called by muse, mutect2
- SPIDR | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 81/602 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs550506526, COSV52395138; called by muse, mutect2, varscan2
- TBC1D9 | c.1913G>C p.R638T | Missense Mutation (SNP) | VAF 64/465 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV71307756; called by muse, mutect2, varscan2
- TGFBR1 | c.1188C>G p.F396L | Missense Mutation (SNP) | VAF 89/664 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV66625137; called by muse, mutect2, varscan2
- ZBTB43 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 76/685 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV65094505; called by muse, mutect2, varscan2
- ZFHX4 | c.4486G>A p.E1496K | Missense Mutation (SNP) | VAF 88/675 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs771813296, COSV50578928; called by muse, mutect2, varscan2
- AC090517.4 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 16/425 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.339); called by muse, mutect2
- ADAM18 | c.841C>G p.P281A | Missense Mutation (SNP) | VAF 36/355 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.392); called by muse, mutect2
- ARHGAP28 | c.853G>T p.E285* (on ENST00000383472 / NM_001366230.1; = p.E126* on NM_001010000.3) | Nonsense Mutation (SNP) | VAF 38/365 reads (10%) | called by muse, mutect2
- CLEC3B | c.105G>C p.K35N | Missense Mutation (SNP) | VAF 74/638 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- G6PC | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 42/708 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2
- GOLGA6A | c.1852G>C p.E618Q | Missense Mutation (SNP) | VAF 12/392 reads (3%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); called by muse, mutect2
- GPR82 | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 90/687 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ICE1 | c.5119G>A p.E1707K | Missense Mutation (SNP) | VAF 84/558 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- KIAA1522 | c.2606C>T p.S869L (on ENST00000373480 / NM_001198972.2; = p.S928L on NM_020888.3) | Missense Mutation (SNP) | VAF 80/457 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- MAGI1 | c.3526G>A p.E1176K (on ENST00000402939 / NM_001033057.2; = p.E1205K on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/597 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- NBAS | c.661C>G p.Q221E | Missense Mutation (SNP) | VAF 32/522 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.754); called by muse, mutect2
- NBPF26 | c.1637C>T p.A546V (on ENST00000620612; = p.A284V on NM_001351372.1) | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- NIPAL3 | c.934A>T p.I312F | Missense Mutation (SNP) | VAF 94/884 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NT5DC3 | c.1395-1G>A p.X465_splice | Splice Site (SNP) | VAF 18/238 reads (8%) | called by muse, mutect2
- OPCML | c.1033T>G p.F345V | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- RAD54L2 | c.1560C>A p.F520L | Missense Mutation (SNP) | VAF 73/533 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RB1 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 165/1029 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RFX6 | c.563C>G p.S188* | Nonsense Mutation (SNP) | VAF 122/688 reads (18%) | called by muse, mutect2, varscan2
- SETD5 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 32/940 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- SLC47A1 | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 51/893 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2
- SLC4A1 | c.221G>C p.R74T | Missense Mutation (SNP) | VAF 138/744 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- STX2 | c.812C>G p.S271* | Nonsense Mutation (SNP) | VAF 64/582 reads (11%) | called by muse, mutect2, varscan2
- TOP2B | c.2941_2942insG p.Y981* (on ENST00000264331 / NM_001330700.2; = p.Y976* on NM_001068.3) | Nonsense Mutation (INS) | VAF 140/531 reads (26%) | called by mutect2, pindel, varscan2
- TRAPPC11 | c.1467G>A p.W489* | Nonsense Mutation (SNP) | VAF 90/510 reads (18%) | called by muse, mutect2, varscan2
- TTN | c.55288G>A p.E18430K (on ENST00000591111; = p.E11006K on NM_003319.4) | Missense Mutation (SNP) | VAF 54/342 reads (16%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UGT2B7 | c.1213C>G p.H405D | Missense Mutation (SNP) | VAF 81/805 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ZNF789 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 20/782 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2
- ABO | c.573C>T p.I191= | Silent (SNP) | VAF 28/618 reads (5%) | called by muse, mutect2
- ACKR3 | c.807C>T p.H269= | Silent (SNP) | VAF 73/470 reads (16%) | catalogued as rs757104529, COSV56020563; called by muse, mutect2, varscan2
- ADAD2 | c.987C>G p.L329= (on ENST00000315906 / NM_001145400.2; = p.L411= on NM_139174.4) | Silent (SNP) | VAF 134/842 reads (16%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.31C>T p.L11= | Silent (SNP) | VAF 21/653 reads (3%) | catalogued as COSV100667286, COSV62372193; called by muse, mutect2
- CCDC39 | c.342G>A p.K114= | Silent (SNP) | VAF 68/538 reads (13%) | catalogued as COSV56489373; called by muse, mutect2, varscan2
- CDC14C | c.477T>C p.Y159= (on ENST00000428251; = p.Y52= on NM_152627.3) | Silent (SNP) | VAF 208/797 reads (26%) | catalogued as rs750835605; called by muse, mutect2, varscan2
- CEP170B | c.3588C>T p.F1196= (on ENST00000453495; = p.F1125= on NM_015005.3) | Silent (SNP) | VAF 49/326 reads (15%) | called by muse, mutect2, varscan2
- EPB41 | c.159G>A p.L53= | Silent (SNP) | VAF 119/775 reads (15%) | called by muse, mutect2, varscan2
- HYLS1 | c.558G>C p.L186= | Silent (SNP) | VAF 62/530 reads (12%) | called by muse, mutect2, varscan2
- MAGEL2 | c.1755C>T p.I585= | Silent (SNP) | VAF 80/697 reads (11%) | catalogued as rs1367329596, COSV58568402; called by muse, mutect2, varscan2
- MYEF2 | c.444C>T p.F148= | Silent (SNP) | VAF 30/228 reads (13%) | catalogued as COSV99981137; called by muse, mutect2, varscan2
- NEDD1 | c.1206G>C p.G402= | Silent (SNP) | VAF 69/525 reads (13%) | called by muse, mutect2, varscan2
- NOD1 | c.1734C>A p.L578= | Silent (SNP) | VAF 87/661 reads (13%) | called by muse, mutect2
- OR2J3 | c.759C>A p.L253= | Silent (SNP) | VAF 105/668 reads (16%) | called by muse, mutect2, varscan2
- PCDHGB1 | c.753C>T p.N251= | Silent (SNP) | VAF 133/423 reads (31%) | catalogued as rs767340665, COSV53929025; called by muse, mutect2, varscan2
- PLCG2 | c.369C>T p.L123= | Silent (SNP) | VAF 134/739 reads (18%) | called by muse, mutect2, varscan2
- PPARGC1A | c.1302G>A p.L434= | Silent (SNP) | VAF 24/652 reads (4%) | called by muse, mutect2
- PRICKLE1 | c.477C>T p.F159= | Silent (SNP) | VAF 75/522 reads (14%) | called by muse, mutect2, varscan2
- PXDNL | c.3366G>A p.L1122= | Silent (SNP) | VAF 29/724 reads (4%) | catalogued as rs1478548027; called by muse, mutect2
- TG | c.1422G>T p.G474= | Silent (SNP) | VAF 221/813 reads (27%) | catalogued as COSV55091300; called by muse, mutect2, varscan2
- TRAPPC9 | c.1129C>A p.R377= | Silent (SNP) | VAF 80/625 reads (13%) | catalogued as CM099332; called by mutect2, varscan2
- TSC2 | c.3733C>A p.R1245= | Silent (SNP) | VAF 87/468 reads (19%) | catalogued as rs777489742; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSC2 | c.5130C>T p.F1710= | Silent (SNP) | VAF 95/471 reads (20%) | catalogued as rs760978505, COSV51916762; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- UHMK1 | c.57C>T p.F19= | Silent (SNP) | VAF 80/582 reads (14%) | catalogued as COSV56420195, COSV56420580; called by muse, varscan2
- WNT2 | c.531G>A p.R177= | Silent (SNP) | VAF 107/669 reads (16%) | catalogued as rs746829775, COSV55414468; called by muse, mutect2, varscan2
- ZNF638 | c.5421G>A p.G1807= | Silent (SNP) | VAF 150/947 reads (16%) | catalogued as rs201030892; called by muse, mutect2, varscan2
- ZNF813 | c.579G>A p.G193= | Silent (SNP) | VAF 180/600 reads (30%) | catalogued as COSV101124699; called by muse, mutect2
- AQR | c.330+75G>A | Intron (SNP) | VAF 4/84 reads (5%) | called by muse, mutect2
- C2CD5 | c.-8C>T | 5'UTR (SNP) | VAF 108/718 reads (15%) | called by muse, mutect2, varscan2
- CAMTA2 | c.-64-576G>A | Intron (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2
- KRT74 | c.1135-22C>G | Intron (SNP) | VAF 59/404 reads (15%) | called by muse, mutect2, varscan2
- L3HYPDH | c.508+50G>A | Intron (SNP) | VAF 27/148 reads (18%) | called by muse, mutect2, varscan2
- LRRK2 | c.*90C>T | 3'UTR (SNP) | VAF 7/186 reads (4%) | catalogued as rs1239020738; called by muse, mutect2
- MAF | c.-4G>A | 5'UTR (SNP) | VAF 51/198 reads (26%) | called by mutect2, varscan2
- MAP3K4 | c.152+61C>G | Intron (SNP) | VAF 93/504 reads (18%) | called by muse, mutect2, varscan2
- NXF3 | c.-97C>T | 5'UTR (SNP) | VAF 9/167 reads (5%) | called by muse, mutect2
- P2RX6 | c.*208G>A | 3'UTR (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2
- P2RY11 | c.*481G>C | 3'UTR (SNP) | VAF 18/202 reads (9%) | catalogued as COSV99461378; called by muse, mutect2
- PARP9 | c.2185+74G>A | Intron (SNP) | VAF 38/298 reads (13%) | called by muse, mutect2, varscan2
- RNF103 | c.-919G>T | 5'UTR (SNP) | VAF 75/610 reads (12%) | catalogued as rs1000985194; called by muse, mutect2, varscan2
- TCF3 | c.1327-27G>A | Intron (SNP) | VAF 95/492 reads (19%) | called by muse, mutect2
- TMEM132D | c.-87C>T | 5'UTR (SNP) | VAF 5/108 reads (5%) | catalogued as rs1483625621; called by muse, mutect2
- VIPR2 | c.357+6905C>T | Intron (SNP) | VAF 185/557 reads (33%) | catalogued as rs568908306, COSV51103614; called by muse, mutect2, varscan2
